Surgical pathology report (de-identified scan), TCGA case TCGA-86-7953, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-7953-01A (Primary Tumor).

[page 1 of 4]
Case ID	OpenClinica ID	Gross Description	Microscopic Description

[page 2 of 4]
Diagnosis Details	Comments

[page 3 of 4]
Formatted Path Report

LUNG TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor site: Lung

Tumor size: 2.5 x 1.5 x 3 cm

Histologic type: Bronchiolo-alveolar adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Laterality

Left-upper

[page 4 of 4]
Excision date

© 2004 Blackwell Publishing Ltd
Journal of Internal Medicine 255: 101–108

Source: NCI Genomic Data Commons file 18171b04-e11b-41f8-8df0-c72c60a8a9d7 (TCGA-86-7953.1AF715D0-9B4B-444F-B93E-53478CDE8E58.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).